TCGA case TCGA-EM-A4FF — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: University Health Network. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b7bafe7f-295c-4598-9cc8-49d785bd2218

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 40 years; Vital status: Alive.

Diagnoses (3)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 40.5 years (14,796 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 2,573 days (7.0 years); Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 4; Measurement unit: Centimeters; Tumor depth measurement: 0.9; Tumor length measurement: 1.5; Tumor width measurement: 1.1.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 179 days; Days to treatment end: 179 days; Treatment dose: 100 mCi; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 2,078 days (5.7 years); Days to treatment end: 2,078 days (5.7 years); Treatment dose: 125 mCi; Treatment outcome: Complete Response; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 100 mCi; Pretreatment: Thyroxine Withdrawal.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 100; Prescribed dose units: mCi; Pretreatment: Thyroxine Withdrawal; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation, External Beam.
2. Recurrence of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Lymph node, NOS. Age at diagnosis: 45.4 years (16,581 days); Days to diagnosis: 1,785 days (4.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,855 days (5.1 years).
   Treatment given: Treatment type: I-131 Radiation Therapy; Initial disease status: Recurrent Disease; Treatment dose: 125; Prescribed dose: 125; Pretreatment: rhTSH.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation, External Beam, for recurrent disease.
3. Recurrence of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Lymph node, NOS. Age at diagnosis: 45.6 years (16,651 days); Days to diagnosis: 1,855 days (5.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,855 days (5.1 years).
   Treatment given: Treatment type: I-131 Radiation Therapy; Initial disease status: Recurrent Disease; Treatment dose: 229; Prescribed dose: 125; Pretreatment: Thyroxine Withdrawal.

Follow-up (6 entries)
- Day 1,785 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 1,785 days (4.9 years); Evidence of recurrence type: Histologic Confirmation; Histologic progression: No.
- Day 1,855 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 1,855 days (5.1 years); Evidence of recurrence type: Histologic Confirmation; Histologic progression: No.
- Days to follow up: 2,149 days (5.9 years); Disease response: Tumor Free.
- Days to follow up: 2,573 days (7.0 years); Disease response: Tumor Free.
- Imaging type: Ultrasound; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Follow-up contact recording only the day: within 3 months of surgery.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EM-A4FF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 50 mg.
  Slide TCGA-EM-A4FF-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-EM-A4FF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EM-A4FF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Left lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: No; I 131 radiation first treatment dose: 100 mCI.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation first treatment dose: 100mcI; I 131 radiation treatment cumulative dose: 100mcI; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,573 days; disease-specific survival: no event (censored), 2,573 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,785 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EM-A4FF-01A-11D-A256-01): tumor purity 0.59, ploidy 2, whole-genome doublings 0.
